Somatic mutation profile of tumor specimen MP2PRT-PAVTYD-TBP1-A (aliquot MP2PRT-PAVTYD-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVTYD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (684 days).
Specimen MP2PRT-PAVTYD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a703748b-3526-4354-9383-5e872acb661e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTYD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTYD-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74745048-200f-4973-a22c-5f30054d5d58

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as COSV55854648; called by muse, mutect2, varscan2
- ARHGEF11 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 25/466 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100810363; called by muse, mutect2
- GAL3ST3 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 73/616 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1334590011; called by muse, mutect2, varscan2
- TAF11L14 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1305051131; called by muse, mutect2, varscan2
- ABCC5 | c.1942_1943insTA p.E648Vfs*12 | Frame Shift Ins (INS) | VAF 33/250 reads (13%) | called by mutect2, pindel, varscan2
- DCAF6 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- GPR37 | c.1419G>C p.E473D | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- HECW1 | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 32/466 reads (7%) | called by muse, mutect2
- IFIT3 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); called by muse, mutect2
- MTF1 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DACT2 | c.2025G>A p.P675= | Silent (SNP) | VAF 76/494 reads (15%) | catalogued as rs1471495887; called by muse, mutect2, varscan2
- DERL3 | c.108C>T p.L36= | Silent (SNP) | VAF 59/598 reads (10%) | called by muse, mutect2, varscan2
- LHX1 | c.543G>T p.R181= | Silent (SNP) | VAF 35/840 reads (4%) | called by muse, mutect2
- PCDH11X | c.3111A>T p.P1037= | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- PCDHB1 | c.873G>A p.T291= | Silent (SNP) | VAF 19/456 reads (4%) | catalogued as rs1172005666, COSV60631017; called by muse, mutect2
- IGHV3-13 | chr14:106129539 ins GCCTGA | 3'Flank (INS) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- ZNF578 | chr19:52451228 G>T | 5'Flank (SNP) | VAF 32/273 reads (12%) | called by muse, mutect2, varscan2
